Somatic mutation profile of tumor specimen BA2598D (aliquot aq-BA2598D) from BEATAML1.0 case 2417, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.3 years (26,412 days).
Specimen BA2598D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1b30130d-e2eb-4031-9a5f-bd0d85c54cfc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2558D (Solid Tissue Normal), aliquot aq-BA2558D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4acb3bb7-202c-48be-a7d8-a737f35506ab

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, 5'Flank 2, 5'UTR 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2503G>C p.D835H | Missense Mutation (SNP) | VAF 40/225 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913488, COSV54042116, COSV54042636, COSV54045151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FCN1 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 70/154 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.052); catalogued as rs141157367; called by muse, varscan2
- KRTAP1-1 | c.32T>A p.F11Y | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (1); PolyPhen possibly damaging (0.741); catalogued as rs768488910, COSV60398084; called by muse, mutect2
- PLD3 | c.395A>G p.N132S | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV62925880; called by muse, mutect2, varscan2
- QSER1 | c.3243A>C p.Q1081H (on ENST00000399302; = p.Q1210H on NM_001076786.3) | Missense Mutation (SNP) | VAF 73/137 reads (53%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs1265898287; called by muse, mutect2, varscan2
- SMURF2 | c.484G>A p.G162S | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs1555687041; called by muse, mutect2, varscan2
- TET2 | c.3898T>C p.F1300L | Missense Mutation (SNP) | VAF 75/182 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54431583; called by muse, mutect2, varscan2
- LENG8 | c.2282C>A p.S761Y | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.013); called by muse, mutect2
- BRD1 | c.1590C>T p.H530= | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as rs142998918; called by muse, varscan2
- LHFPL4 | c.-2C>A | 5'UTR (SNP) | VAF 4/31 reads (13%) | catalogued as COSV99805647; called by muse, mutect2
- PKD1L2 | chr16:81139712 G>A | 5'Flank (SNP) | VAF 16/41 reads (39%) | catalogued as rs780764446; called by muse, mutect2, varscan2
- TSPOAP1 | chr17:58331287 G>T | 5'Flank (SNP) | VAF 31/61 reads (51%) | called by muse, mutect2, varscan2
